TCGA case TCGA-V4-A9EW — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6be5176c-4980-4663-adff-d04f05737da0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 44 years; Year of birth: 1968; Vital status: Dead; Days to death: 1,585 days (4.3 years); Year of death: 2016.

Diagnoses (3)
1. Mixed epithelioid and spindle cell melanoma (the primary disease): ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 44.2 years (16,140 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,585 days (4.3 years); Sites of involvement: Eye, Choroid.
   Pathology details: Consistent pathology review: No; Epithelioid cell percent range: 31-60%; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: 31-60%; Tumor depth measurement: 9.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 19.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -21 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fotemustine; Days to treatment start: 417 days (1.1 years); Days to treatment end: 458 days (1.3 years); Number of cycles: 1; Treatment dose: 147 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Clinical Trial Agent; Treatment intent type: Salvage; Days to treatment start: 499 days (1.4 years); Days to treatment end: 1,191 days (3.3 years); Number of cycles: 26; Treatment outcome: No Response; Reason treatment ended: Other; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Dacarbazine; Treatment intent type: Salvage; Days to treatment start: 1,059 days (2.9 years); Days to treatment end: 1,568 days (4.3 years); Number of cycles: 3; Treatment dose: 1,179 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Nivolumab; Treatment intent type: Salvage; Days to treatment start: 1,219 days (3.3 years); Days to treatment end: 1,268 days (3.5 years); Number of cycles: 4; Treatment dose: 150 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mixed epithelioid and spindle cell melanoma), site: Liver. Age at diagnosis: 44.7 years (16,337 days); Days to diagnosis: 197 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
3. Metastasis of diagnosis 1 (Mixed epithelioid and spindle cell melanoma), site: Liver. Age at diagnosis: 45.2 years (16,521 days); Days to diagnosis: 381 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (7 entries)
- Days to follow up: -32 days; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: -32 days.
- Day 197 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 197 days.
- Day 381 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 381 days (1.0 years).
- Days to follow up: 774 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 914 days (2.5 years); Disease response: With Tumor.
- Days to follow up: 1,211 days (3.3 years); Disease response: With Tumor.
- Days to follow up: 1,585 days (4.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 40.

Other clinical attributes
- Eye color: Blue.
- Timepoint category: Initial Diagnosis; Weight: 51 kg; Height: 156 cm; BMI: 21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 30 mg.
  Slide TCGA-V4-A9EW-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Spindle Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 1 loss.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness: 9 mm; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,211 days; disease-specific survival: no event (censored), 1,211 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 197 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EW-01A-11D-A39V-01): tumor purity 0.68, ploidy 1.97, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3q; Gain 6p
- days to imaging: 1358
- days to metastasis: -32
- days to outcome: 1362
- days to pharm therapy imaging 1: 451
- days to pharm therapy imaging 2: 1191
- days to pharm therapy imaging 4: 1291
- days to procedure 1: -21
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- drug name 1: fotemustin
- drug name 2: PKC inh
- drug name 3: nivolizumab
- drug name 4: deticene
- imaging type: CT
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- number cycles 1: 1
- number cycles 3: 4
- number cycles 4: 3
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy dose units 1: mg
- pharm therapy dose units 3: mg
- pharm therapy dose units 4: mg
- pharm therapy evaluated by imaging 1: yes
- pharm therapy evaluated by imaging 4: Yes
- pharm therapy imaging type 1: CT
- pharm therapy imaging type 2: MRI
- pharm therapy imaging type 4: MRI
- pharm therapy status 1: treatment change
- pharm therapy status 2: treatment change
- pharm therapy status 3: treatment discontinued
- pharm therapy status 4: treatment discontinued
- pharm therapy status reason 1: Lack of Response
- pharm therapy status reason 2: Lack of Response
- pharm therapy status reason 3: Lack of Response
- pharm therapy status reason 4: Lack of Response
- regimen name 2: phase I COEB
- resection status 1: R0
- smoking status: non-smoker
- staging system: AJCC
- t stage: T4b
- test methodology: aCGH
- test result: low risk
- unresectable 1: no
